Somatic mutation profile of tumor specimen 558333b0-ea23-4303-9e3c-4932b1 (aliquot 558333b0-ea23-4303-9e3c-4932b1_D8) from CPTAC case 01OV046, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV.
Specimen 558333b0-ea23-4303-9e3c-4932b1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26f1b2aa-5f0e-49e1-b501-23b20193787a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 238d15a7-4791-4cef-945a-48c5e4 (Blood Derived Normal), aliquot 238d15a7-4791-4cef-945a-48c5e4_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86bc58f8-9cdc-40f7-8727-9db14e2468da

The open-access MAF lists 127 somatic variants for this specimen: 89 protein-altering or splice-affecting, 22 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 22, Intron 7, 3'UTR 4, Frame Shift Del 4, Splice Site 3, 5'Flank 2, Nonsense Mutation 2, Nonstop Mutation 1, Splice Region 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMHR2 | c.56C>G p.P19R | Missense Mutation (SNP) | VAF 89/408 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780240281; called by muse, mutect2, varscan2
- ARIH2 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.189); catalogued as COSV62704031; called by muse, mutect2, varscan2
- BRCA1 | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 117/151 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as CM1312748; called by muse, mutect2, varscan2
- CAND2 | c.3083G>A p.R1028H | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs536119459; called by muse, mutect2, varscan2
- CAVIN2 | c.698G>T p.R233I | Missense Mutation (SNP) | VAF 116/446 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs745460697, COSV58424027, COSV58424701; called by muse, mutect2, varscan2
- CDH18 | c.1637C>A p.T546K | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV56904744; called by muse, mutect2, varscan2
- COL25A1 | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV101210990; called by muse, mutect2, varscan2
- EFCAB6 | c.3777G>C p.Q1259H | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV53058288; called by muse, mutect2, varscan2
- FAM155B | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 161/558 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52936358; called by muse, mutect2, varscan2
- GGA3 | c.718T>A p.S240T (on ENST00000537686 / NM_138619.4; = p.S207T on NM_014001.5) | Missense Mutation (SNP) | VAF 54/195 reads (28%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.705); catalogued as rs1052944823; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV56091309; called by muse, mutect2, varscan2
- KCNC1 | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.51); catalogued as rs1283149900, COSV99789299; called by muse, mutect2, varscan2
- MAB21L3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs138934890; called by muse, mutect2, varscan2
- MAST1 | c.4396C>G p.L1466V | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV52256003; called by muse, varscan2
- MYO3A | c.2114G>C p.S705T | Missense Mutation (SNP) | VAF 77/207 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.282); catalogued as COSV56349809; called by muse, mutect2, varscan2
- NMRAL1 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 117/410 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs751342170; called by muse, mutect2, varscan2
- PTOV1 | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55587307; called by muse, mutect2, varscan2
- SLC26A1 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs202108786; called by muse, mutect2, varscan2
- SNAP91 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs1295717061, COSV52130234; called by muse, mutect2, varscan2
- TLX3 | c.417C>A p.F139L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV51539973; called by muse, mutect2, varscan2
- TRAPPC9 | c.2699G>T p.S900I | Missense Mutation (SNP) | VAF 90/779 reads (12%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs1470037371; called by muse, mutect2, varscan2
- TSHZ3 | c.2364G>T p.Q788H | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53672922; called by muse, mutect2, varscan2
- ZBTB41 | c.2294C>G p.S765C | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as COSV66358778, COSV66359174; called by muse, mutect2, varscan2
- ZNF831 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776840206; called by muse, mutect2, varscan2
- ACOT6 | c.469A>G p.R157G | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- ACSS1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 51/302 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- AMER1 | c.1479T>G p.D493E | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.545); called by muse, mutect2
- ARHGEF26 | c.2614T>C p.*872Qext*23 | Nonstop Mutation (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- ATP10D | c.2044A>G p.S682G | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- BRSK1 | c.94G>C p.G32R | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTAF1 | c.3784A>T p.I1262F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- C19orf44 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CBLL1 | c.1319G>C p.S440T | Missense Mutation (SNP) | VAF 72/242 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by mutect2, varscan2
- CCP110 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- COL11A1 | c.2878A>T p.T960S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DMBT1 | c.1780T>A p.S594T | Missense Mutation (SNP) | VAF 77/158 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAJC9 | c.294G>T p.E98D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- DST | c.14065G>T p.G4689C (on ENST00000361203 / NM_001374722.1; = p.G2277C on NM_015548.5) | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EML6 | c.3245A>G p.K1082R | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- EXD3 | c.1767G>C p.E589D | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FGD1 | c.2194_2197del p.E732Sfs*130 | Frame Shift Del (DEL) | VAF 109/533 reads (20%) | called by mutect2, pindel, varscan2
- FLACC1 | c.1242T>G p.I414M | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FNIP1 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- GOLGA6L6 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 33/94 reads (35%) | called by mutect2, varscan2
- GPR39 | c.719T>G p.F240C | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IL4R | c.1220C>G p.T407R | Missense Mutation (SNP) | VAF 82/447 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- KCNMB4 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LTBP4 | c.200_205+35del p.X67_splice (on ENST00000308370 / NM_001042544.1; = p.X24_splice on NM_003573.2) | Splice Site (DEL) | VAF 30/163 reads (18%) | called by mutect2, pindel, varscan2
- MARF1 | c.1030G>T p.G344* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- MID1 | c.218T>A p.L73H | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MID1IP1 | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NCOA7 | c.1765C>G p.L589V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOL12 | c.125_132del p.K42Sfs*3 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel*, varscan2
- NRIP2 | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NUP188 | c.202G>C p.A68P | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OTUD4 | c.629+8_629+29delinsAG | Splice Region (DEL) | VAF 28/75 reads (37%) | called by pindel, varscan2*
- PCDH12 | c.2241C>G p.N747K | Missense Mutation (SNP) | VAF 101/630 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PCDHB8 | c.1140_1162del p.K381Gfs*38 | Frame Shift Del (DEL) | VAF 84/786 reads (11%) | called by mutect2, pindel
- PDE1C | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- PNLDC1 | c.239T>A p.F80Y | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, varscan2
- POTEG | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 60/1240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PRDM15 | c.1330A>T p.S444C | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PSD | c.1421C>T p.A474V | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- REPS2 | c.1270G>C p.D424H | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RGPD4 | c.4337T>C p.V1446A | Missense Mutation (SNP) | VAF 28/526 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); called by muse, mutect2
- RPH3AL | c.14T>C p.I5T | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- S1PR2 | c.184A>G p.S62G | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SH3GLB1 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC37A1 | c.211G>T p.G71W | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- SLC7A13 | c.950C>G p.A317G | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.236); called by muse, mutect2
- SORT1 | c.709-1G>C p.X237_splice | Splice Site (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- SOX30 | c.1768C>G p.H590D | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SPTBN5 | c.761T>A p.L254Q | Missense Mutation (SNP) | VAF 160/453 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STK10 | c.2062A>C p.T688P | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBCCD1 | c.799A>C p.N267H | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TCAF1 | c.2506C>G p.L836V | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2
- TEX44 | c.138G>C p.W46C | Missense Mutation (SNP) | VAF 75/564 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- TEX52 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TNS1 | c.4141A>T p.S1381C | Missense Mutation (SNP) | VAF 36/457 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TNXB | c.5945G>T p.R1982L (on ENST00000647633; = p.R1735L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- UGT2B17 | c.44G>C p.S15T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- USP15 | c.2222T>A p.L741H (on ENST00000280377 / NM_001351159.2; = p.L712H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, varscan2
- VEGFC | c.1166_1168del p.T389del | In Frame Del (DEL) | VAF 21/63 reads (33%) | called by mutect2, pindel, varscan2
- WDR97 | c.3975C>G p.F1325L | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- XPNPEP2 | c.1856A>G p.Q619R | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF224 | c.931A>C p.T311P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ZNF26 | c.828C>G p.H276Q | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF485 | c.1230_1276del p.Y410* | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel
- ZNF862 | c.475C>A p.L159M | Missense Mutation (SNP) | VAF 113/442 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP9 | c.2145A>G p.P715= (on ENST00000393797 / NM_001319850.2; = p.P696= on NM_032496.4) | Silent (SNP) | VAF 34/172 reads (20%) | catalogued as rs540675302; called by muse, mutect2, varscan2
- CELSR2 | c.1587T>C p.A529= | Silent (SNP) | VAF 49/592 reads (8%) | called by muse, mutect2
- CHRNA2 | c.963C>A p.T321= | Silent (SNP) | VAF 285/391 reads (73%) | called by muse, mutect2, varscan2
- ENO3 | c.825G>A p.K275= | Silent (SNP) | VAF 107/298 reads (36%) | called by muse, mutect2, varscan2
- GDAP1 | c.321C>A p.P107= | Silent (SNP) | VAF 70/496 reads (14%) | called by mutect2, varscan2
- HRH2 | c.375G>T p.R125= | Silent (SNP) | VAF 360/452 reads (80%) | catalogued as rs572573041; called by muse, mutect2, varscan2
- MAP1B | c.6300T>G p.S2100= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV57107377; called by muse, mutect2
- MARF1 | c.1029T>C p.A343= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- MRPL44 | c.930T>C p.N310= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1457163053; called by muse, mutect2, varscan2
- NCAPG | c.1617A>C p.T539= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- NIPBL | c.2679T>A p.P893= | Silent (SNP) | VAF 117/318 reads (37%) | called by muse, mutect2, varscan2
- NSUN5 | c.969A>T p.A323= | Silent (SNP) | VAF 27/180 reads (15%) | called by muse, mutect2, varscan2
- OR5T3 | c.330A>C p.A110= | Silent (SNP) | VAF 117/393 reads (30%) | called by muse, mutect2, varscan2
- PCNX2 | c.5286C>T p.V1762= | Silent (SNP) | VAF 69/272 reads (25%) | catalogued as COSV50834883; called by muse, mutect2, varscan2
- POMGNT2 | c.390C>T p.F130= | Silent (SNP) | VAF 266/519 reads (51%) | called by muse, mutect2, varscan2
- PTOV1 | c.627C>A p.S209= | Silent (SNP) | VAF 50/318 reads (16%) | called by muse, mutect2, varscan2
- RNF113B | c.282C>T p.Y94= | Silent (SNP) | VAF 66/188 reads (35%) | called by muse, mutect2, varscan2
- SPTBN2 | c.1059G>A p.V353= | Silent (SNP) | VAF 26/400 reads (7%) | catalogued as COSV100019048; called by muse, mutect2
- STRIP1 | c.1923G>T p.V641= | Silent (SNP) | VAF 123/313 reads (39%) | catalogued as COSV63931353; called by muse, mutect2, varscan2
- TDRD15 | c.627A>G p.Q209= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs1352600710; called by muse, mutect2, varscan2
- THSD7B | c.3699G>A p.E1233= (on ENST00000272643; = p.E1231= on NM_001316349.2) | Silent (SNP) | VAF 24/94 reads (26%) | called by muse, mutect2, varscan2
- XKR6 | c.858C>T p.D286= | Silent (SNP) | VAF 121/171 reads (71%) | catalogued as rs373965526, COSV58656630; called by muse, mutect2, varscan2
- AC017104.4 | chr2:231509196 C>A | 5'Flank (SNP) | VAF 98/268 reads (37%) | called by muse, varscan2
- ATP5PF | c.*26A>G | 3'UTR (SNP) | VAF 10/171 reads (6%) | called by muse, mutect2
- C2orf80 | c.573+2539C>A | Intron (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- CD33 | c.924+186_924+217del | Intron (DEL) | VAF 156/302 reads (52%) | called by mutect2, varscan2
- CYP4F12 | c.525+96G>T | Intron (SNP) | VAF 22/242 reads (9%) | called by muse, mutect2
- CYP4F24P | n.365C>T | RNA (SNP) | VAF 52/168 reads (31%) | catalogued as rs750498754; called by muse, mutect2, varscan2
- CYYR1 | c.-108A>T | 5'UTR (SNP) | VAF 46/263 reads (17%) | called by muse, mutect2, varscan2
- FAM207A | chr21:44935032 C>G | 5'Flank (SNP) | VAF 40/342 reads (12%) | called by muse, mutect2, varscan2
- GRK5 | c.148+7202G>T | Intron (SNP) | VAF 94/237 reads (40%) | called by muse, mutect2, varscan2
- KIAA2012 | c.369+1908dup | Intron (INS) | VAF 36/144 reads (25%) | called by mutect2, varscan2
- LCN2 | c.275+79G>A | Intron (SNP) | VAF 126/620 reads (20%) | catalogued as rs779587495; called by mutect2, varscan2
- NT5C3A | c.139-2779T>C | Intron (SNP) | VAF 23/93 reads (25%) | catalogued as rs1428998746; called by muse, mutect2, varscan2
- RPS19 | c.*6A>T | 3'UTR (SNP) | VAF 94/140 reads (67%) | catalogued as COSV99702699; called by muse, mutect2, varscan2
- SNX4 | c.*48C>A | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2
- SULT1A3 | chr16:30206230 G>C | 3'Flank (SNP) | VAF 32/472 reads (7%) | called by muse, mutect2
- VAPB | c.*5572G>T | 3'UTR (SNP) | VAF 98/380 reads (26%) | called by muse, mutect2, varscan2
